Surgical pathology report (de-identified scan), TCGA case TCGA-BR-6564, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site Asterand, specimen TCGA-BR-6564-01A (Primary Tumor).

[page 1 of 2]
Formatted Path Report			
			STOMACH TISSUE CHECKLIST
			Specimen type: Gastrectomy
			Tumor site: Stomach
			Tumor size: 6 x 6 x 1 cm
			Tumor features: Ulcerated
			Histologic type: Adenocarcinoma
			Histologic grade: Poorly differentiated
			Tumor extent: Adjacent structures (specify) - greater omentum
			Lymph nodes: 3/7 positive for metastasis (Intraabdominal 3/7)
			Lymphatic invasion: Not specified
			Venous invasion: Not specified
			Perineural invasion: Not specified
			Margins: Uninvolved
			Evidence of neo-adjuvant treatment: Not specified
			Additional pathologic findings: Not specified
			Comments: None

[page 2 of 2]
Date of Procurement

--	--

Source: NCI Genomic Data Commons file 3f9fba4c-41d7-42d0-858e-ecba53583724 (TCGA-BR-6564.C99A5FA5-94AC-413A-91E1-A3AE5E19318A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).